CCDI case PBCAEC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/94b96a99-9fba-4877-81fb-eae8a4492665

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 3.8 years (1,389 days).

Biospecimens (3 samples)
- Sample 0DMN14: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN1L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN2A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
